FM case AD940 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/0d6269b3-9e66-4d32-b8cb-35196e2489bb

Female, 65.3 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the major salivary gland; specimen biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
